Gene-level copy-number profile of tumor specimen HCM-SANG-1300-C18-01A-01D-A80T-32 from HCMI case HCM-SANG-1300-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-1300-C18-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4093dd34-702b-4483-9379-0f18649bb247.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1300-C18-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/dcc0c2f6-06f7-4658-b732-ae2ad111b51d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 129; copy number 1: 1,953; copy number 2: 14,424; copy number 3: 36,168; copy number 4: 2,569; copy number 5: 1,255; copy number 6: 2,352; copy number 7: 37; copy number 8: 15; copy number 11: 1.

Homozygous deletions (total copy number 0; autosomes only): 129 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:48,532,854–50,023,954, 11 genes (within-gene range 0–2): AGBL4, AL391844.1, BEND5, AL645507.1, AC099788.1, AGBL4-AS1, AGBL4-IT1, AL390023.1, ZNF859P, AL645730.1, MTND2P29.
- chr4:187,532,873–190,092,279, 52 genes: LINC02492, AC097521.1, ADAM20P3, AC108073.1, ZFP42, TRIML2, AC108073.2, RNU6-173P, TRIML1, AC138781.1, LINC02434, AC093789.1, ICE2P1, LINC01060, AC093909.3, AC093909.5, RNU7-192P, AC093909.1, AC093909.6, AC093909.2, LINC02508, AC093909.4, AC122138.1, AC107391.1, AC105924.1, HSP90AA4P, LINC01262, AF250324.1, RNU1-51P, FRG1-DT, LINC01596, FRG1, MLLT10P2, AF146191.2, TUBB7P, RNA5SP174, RNA5SP175, DUX4L9, FRG2, RARRES2P4, AGGF1P1, CLUHP4, DBET, U85056.1, DUX4L8, DUX4L7, DUX4L6, DUX4L5, DUX4L4, DUX4L1, DUX4L3, DUX4L2.
- chr9:63,974,762–64,498,745, 11 genes: AL163540.1, U6, ANKRD20A4P, RNU6-1193P, SNX18P9, CR769776.2, CYP4F25P, CR769776.1, CNN2P3, GXYLT1P6, AL773524.1.
- chr14:45,891,087–46,501,903, 1 gene: LINC00871.
- chr17:18,426,861–18,506,313, 8 genes: KRT17P2, KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2.
- chr18:37,657,135–40,144,504, 18 genes: MIR4318, RPL12P40, AC100781.1, RN7SKP182, RNU6-706P, MIR924HG, AC011139.1, RPL7AP66, MIR924, AC099845.1, MIR5583-2, MIR5583-1, RNU6-1242P, LINC01901, LINC01902, AC011266.1, LINC01477, RPL17P45.
- chr18:50,560,087–53,629,990, 28 genes: MAPK4, AC012433.2, AC012433.1, MRO, HNRNPA3P16, RPL17P46, ME2, Y_RNA, ELAC1, AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P, LINC01630, SS18L2P2, AC109315.1, RSL24D1P9, AC027216.1, RPS8P3, AC016383.1, DCC, AC011155.1, VN1R76P, MIR4528, LINC01917, LINC01919, RPL29P32.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 53 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,330,670–56,116,417, 51 genes, copy number 7–11: LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2, AC092647.5, ZNF713, NIPSNAP2, MRPS17, PSPH, CCT6A, SNORA22B, SNORA15, SUMF2, PHKG1, CHCHD2, NUPR2.
- chr7:62,275,361–62,275,678, 1 gene, copy number 7: AC128676.1.
- chr21:24,306,939–24,547,942, 1 gene, copy number 7 (within-gene range 1–7): LINC01684.

Autosomal genes at a single copy (total copy number 1): 1,441. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
